Somatic mutation profile of tumor specimen MP2PRT-PATIJL-TMP1-A (aliquot MP2PRT-PATIJL-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PATIJL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.9 years (2,510 days).
Specimen MP2PRT-PATIJL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72e6b04e-0640-4fcd-a23f-38170fade6dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATIJL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATIJL-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a7e81e4-c25e-42a4-804c-f1b4dbbf56ab

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 12, Silent 3, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP8A2 | c.2314G>A p.A772T | Missense Mutation (SNP) | VAF 26/616 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764092726, COSV99681846; called by muse, mutect2
- CDH10 | c.619C>G p.P207A | Missense Mutation (SNP) | VAF 123/259 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52591639; called by muse, mutect2, varscan2
- FLG | c.11840G>A p.R3947H | Missense Mutation (SNP) | VAF 131/333 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs771010160, COSV64243006; called by muse, mutect2, varscan2
- FPGT | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 79/182 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV100907184; called by muse, mutect2, varscan2
- GPX6 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 105/257 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.267); catalogued as rs752759844; called by muse, mutect2, varscan2
- OR51G2 | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 265/553 reads (48%) | catalogued as COSV58993249; called by muse, mutect2, varscan2
- SCN5A | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 158/372 reads (42%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs45627438, CM100657; ClinVar: not provided / uncertain significance; called by muse, varscan2
- TNK1 | c.1322C>T p.T441M (on ENST00000576812 / NM_001251902.2; = p.T436M on NM_003985.5) | Missense Mutation (SNP) | VAF 246/496 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs199995562; called by muse, mutect2, varscan2
- CAND1 | c.1329_1330insGGCC p.K444Gfs*14 | Frame Shift Ins (INS) | VAF 123/247 reads (50%) | called by mutect2, pindel*, varscan2*
- IGHV3-73 | chr14:106802685 CACTGTGTGTCT>TGTG | Missense Mutation (DEL) | VAF 94/222 reads (42%) | called by pindel, varscan2*
- IGKV2D-30 | chr2:89937679 TCCCAC>CAGGG | Missense Mutation (DEL) | VAF 86/102 reads (84%) | called by pindel, varscan2*
- MAGEL2 | c.1654C>A p.P552T | Missense Mutation (SNP) | VAF 285/720 reads (40%) | SIFT tolerated, low confidence (0.11); called by muse, mutect2, varscan2
- MS4A1 | c.568T>C p.F190L | Missense Mutation (SNP) | VAF 59/117 reads (50%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- TYRP1 | c.519T>G p.D173E | Missense Mutation (SNP) | VAF 67/468 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- FAM83H | c.2793G>A p.P931= | Silent (SNP) | VAF 297/625 reads (48%) | catalogued as rs370284848, COSV62029824; called by muse, mutect2, varscan2
- LAMB4 | c.3840T>C p.N1280= | Silent (SNP) | VAF 78/196 reads (40%) | called by muse, mutect2, varscan2
- OLFM1 | c.1086C>T p.S362= (on ENST00000371793 / NM_001282611.2; = p.S344= on NM_014279.5) | Silent (SNP) | VAF 193/412 reads (47%) | catalogued as rs149404483; called by muse, mutect2, varscan2
